Somatic mutation profile of tumor specimen HCM-CSHL-0244-C20-01B (aliquot HCM-CSHL-0244-C20-01B-01D-A78L-36) from HCMI case HCM-CSHL-0244-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,290 days).
Specimen HCM-CSHL-0244-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97eee0de-da1c-4759-ba24-577ea6893880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0244-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0244-C20-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cdfbe78-bf16-42fc-b952-d68ba4975fda

The open-access MAF lists 128 somatic variants for this specimen: 91 protein-altering or splice-affecting, 22 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 22, Intron 11, Nonsense Mutation 6, Frame Shift Del 5, RNA 3, Splice Site 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 45/151 reads (30%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 47/253 reads (19%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- DMD | c.9568C>T p.R3190* | Nonsense Mutation (SNP) | VAF 185/284 reads (65%) | catalogued as rs104894797, CM980563, COSV58926460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>G p.R479G (on ENST00000281708 / NM_001349798.2; = p.R399G on NM_018315.5) | Missense Mutation (SNP) | VAF 157/286 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747241612, COSV55894141, COSV55894999, COSV55908957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 202/420 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 107/229 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TSC2 | c.5034C>G p.Y1678* | Nonsense Mutation (SNP) | VAF 114/236 reads (48%) | catalogued as rs45467993, CD091169, CM054870, CM091138, COSV51919212, COSV51925323; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.3284G>T p.G1095V | Missense Mutation (SNP) | VAF 25/339 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67132512; called by muse, mutect2
- ADCY6 | c.1806G>A p.M602I | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs1267999519; called by muse, mutect2, varscan2
- AMPH | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374682461; called by muse, mutect2, varscan2
- ARR3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs145241324; called by muse, mutect2, varscan2
- BRF1 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as rs144088839; called by muse, mutect2, varscan2
- CCER1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100727017; called by muse, mutect2, varscan2
- CEP164 | c.2523G>C p.Q841H | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV99633415; called by muse, mutect2, varscan2
- CSMD1 | c.9874C>T p.L3292F (on ENST00000520002; = p.L3291F on NM_033225.6) | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59297669, COSV59351625; called by muse, mutect2, varscan2
- DAXX | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 92/187 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs766116335, COSV56468596; called by muse, mutect2, varscan2
- EFCAB5 | c.3847G>C p.D1283H | Missense Mutation (SNP) | VAF 84/477 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57925960; called by muse, mutect2, varscan2
- FRS3 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778007945; called by muse, mutect2, varscan2
- HMMR | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.939); catalogued as COSV62373598; called by muse, mutect2, varscan2
- IL27 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs750265879, COSV60489049; called by muse, mutect2, varscan2
- INO80D | c.3del p.M1? | Frame Shift Del (DEL) | VAF 48/290 reads (17%) | catalogued as COSV68960220; called by mutect2, pindel*, varscan2
- INSL4 | c.255C>G p.F85L | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs773741191; called by muse, mutect2, varscan2
- KIAA1614 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs201563384; called by muse, mutect2, varscan2
- KIF27 | c.2578C>T p.R860* | Nonsense Mutation (SNP) | VAF 146/1110 reads (13%) | catalogued as rs779736930, COSV52826113; called by muse, varscan2
- LCT | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs886054866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAN2B2 | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs753542652; called by muse, varscan2
- NEK8 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs746446513; called by muse, mutect2, varscan2
- NOC2L | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58988243; called by muse, mutect2, varscan2
- NUP85 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs901286852; called by muse, mutect2, varscan2
- OBSCN | c.18844G>A p.V6282M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs571898697; called by muse, varscan2
- PCDHA13 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs368888498, COSV56545189; called by muse, mutect2, varscan2
- PCDHA9 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs555417773, COSV65334252; called by muse, mutect2, varscan2
- PCDHGA2 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.086); catalogued as rs763629957, COSV53925943; called by muse, mutect2, varscan2
- PCDHGB6 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1044650685, COSV53942289; called by muse, mutect2, varscan2
- PCLO | c.1659A>C p.Q553H | Missense Mutation (SNP) | VAF 97/504 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as COSV61628865; called by muse, mutect2, varscan2
- PDIA2 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1422449017; called by muse, mutect2, varscan2
- PHYHIPL | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1334090934, COSV65847971, COSV65848163; called by muse, mutect2, varscan2
- PLA2G2D | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs759264281; called by muse, mutect2, varscan2
- RASGRF2 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs750172396, COSV54123410; called by muse, mutect2, varscan2
- REXO1 | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1464362111; called by muse, mutect2, varscan2
- SPTB | c.5237G>A p.R1746Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs764312726, COSV101071852; called by muse, mutect2
- SREBF1 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 111/194 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751476559; called by muse, mutect2, varscan2
- SRSF11 | c.20T>A p.V7D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV63939683; called by muse, mutect2, varscan2
- TMEM130 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs539482079, COSV59557797; called by muse, mutect2, varscan2
- TNIP2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs746392986, COSV59569234; called by muse, mutect2, varscan2
- TRIM60 | c.1301G>T p.R434M | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1291728143, COSV61970167; called by muse, mutect2, varscan2
- TTK | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 97/405 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771241505, COSV100036443; called by muse, mutect2, varscan2
- ZFP69B | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1260652671; called by muse, mutect2, varscan2
- ZNF33A | c.2198C>T p.S733L (on ENST00000458705 / NM_006974.3; = p.S734L on NM_006954.2) | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772156469, COSV56724740; called by muse, mutect2, varscan2
- ZNF782 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs867502483; called by muse, mutect2, varscan2
- C21orf58 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 57/231 reads (25%) | called by muse, mutect2, varscan2
- C7 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- C8orf74 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1S | c.3746G>T p.R1249L | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CALCR | c.581G>T p.C194F (on ENST00000649521 / NM_001164737.2; = p.C178F on NM_001742.4) | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CCNB3 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 138/215 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDK14 | c.608A>C p.K203T (on ENST00000380050 / NM_001287135.2; = p.K185T on NM_012395.3) | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.725); called by muse, varscan2
- CDK9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.221); called by muse, mutect2
- CST1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 57/283 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DGKE | c.484del p.T162Qfs*7 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | called by mutect2, varscan2
- DNAH10 | c.12086C>A p.T4029K (on ENST00000409039; = p.T3968K on NM_207437.3) | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM135B | c.1329C>A p.D443E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- FBF1 | c.1112C>T p.P371L (on ENST00000586717; = p.P385L on NM_001319193.1) | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD2 | c.1628C>A p.P543Q | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- GJC2 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- H2AC6 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSP90AA1 | c.1423G>T p.V475F | Missense Mutation (SNP) | VAF 91/426 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- KIAA1614 | c.3478C>T p.P1160S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MPHOSPH9 | c.2984del p.P995Qfs*24 | Frame Shift Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- NELL1 | c.1801G>C p.A601P | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.601); called by muse, mutect2
- NKX1-1 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR4Q2 | c.899_900+2del p.X300_splice | Splice Site (DEL) | VAF 22/104 reads (21%) | called by mutect2, pindel, varscan2
- OTOP3 | c.586T>G p.W196G | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- PIGB | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PKP4 | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 76/517 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PXDNL | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- RBM4 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SKOR1 | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC12A2 | c.1398dup p.G467Wfs*3 | Frame Shift Ins (INS) | VAF 69/318 reads (22%) | called by mutect2, pindel, varscan2
- SLC4A1AP | c.2198_2199del p.P733Lfs*6 | Frame Shift Del (DEL) | VAF 33/204 reads (16%) | called by mutect2, pindel, varscan2
- SORL1 | c.3618_3619del p.C1206Wfs*13 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- SRCAP | c.8644T>C p.S2882P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX4 | c.1473C>A p.F491L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- THRA | c.121+1G>A p.X41_splice | Splice Site (SNP) | VAF 27/207 reads (13%) | called by muse, mutect2, varscan2
- THSD7A | c.3152G>T p.C1051F | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TK1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TRIM49 | c.360G>T p.E120D | Missense Mutation (SNP) | VAF 36/516 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- WNT3A | c.407G>C p.C136S | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFHX4 | c.7970G>A p.R2657Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF479 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 173/665 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZNF878 | c.1058A>C p.D353A | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ABCA13 | c.12609G>T p.L4203= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
- ACSBG1 | c.1170G>A p.A390= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as rs372203439; called by muse, mutect2, varscan2
- AGPAT4 | c.240C>T p.R80= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as rs370375430; called by muse, mutect2, varscan2
- AKR7A3 | c.954C>T p.A318= | Silent (SNP) | VAF 60/255 reads (24%) | catalogued as COSV100853832; called by muse, mutect2, varscan2
- BCOR | c.864G>A p.P288= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs1409344460; called by muse, mutect2, varscan2
- EP300 | c.5595C>T p.T1865= | Silent (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- FAM186A | c.4644C>T p.V1548= | Silent (SNP) | VAF 36/77 reads (47%) | called by muse, varscan2
- G6PD | c.1272C>T p.Y424= | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as rs186843026; called by muse, mutect2, varscan2
- GCKR | c.1623G>A p.A541= | Silent (SNP) | VAF 94/335 reads (28%) | catalogued as rs146520140; called by muse, mutect2, varscan2
- HAUS5 | c.603C>T p.N201= | Silent (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- KREMEN1 | c.492C>T p.G164= (on ENST00000407188; = p.G166= on NM_032045.5) | Silent (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- LRFN2 | c.1788G>A p.P596= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs988477489; called by muse, mutect2, varscan2
- LRP8 | c.642C>T p.G214= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as rs942018406; called by muse, mutect2, varscan2
- MAK16 | c.69C>T p.T23= | Silent (SNP) | VAF 67/241 reads (28%) | called by muse, mutect2, varscan2
- PPFIA1 | c.2100C>T p.S700= | Silent (SNP) | VAF 25/141 reads (18%) | catalogued as COSV54141947; called by muse, mutect2, varscan2
- PTPRC | c.573G>A p.A191= | Silent (SNP) | VAF 155/673 reads (23%) | catalogued as rs769284265; called by muse, mutect2, varscan2
- SCNN1G | c.1635C>T p.C545= | Silent (SNP) | VAF 151/269 reads (56%) | catalogued as rs778942971, COSV55597992; called by muse, mutect2, varscan2
- SH3GLB2 | c.873C>T p.P291= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs371175794; called by muse, mutect2, varscan2
- TBC1D21 | c.795G>A p.K265= | Silent (SNP) | VAF 47/224 reads (21%) | called by muse, mutect2, varscan2
- THBS4 | c.2247C>T p.N749= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs751024241; called by muse, mutect2, varscan2
- TTN | c.83487T>C p.P27829= (on ENST00000591111; = p.P20405= on NM_003319.4) | Silent (SNP) | VAF 190/510 reads (37%) | called by muse, mutect2, varscan2
- XRN2 | c.1056G>T p.S352= | Silent (SNP) | VAF 91/461 reads (20%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4452G>T | Intron (SNP) | VAF 35/147 reads (24%) | catalogued as rs775018004; called by muse, mutect2, varscan2
- ATG13 | c.790-798G>C | Intron (SNP) | VAF 75/389 reads (19%) | called by muse, mutect2, varscan2
- CYP2B7P | n.567C>T | RNA (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- LINC02817 | n.408C>A | RNA (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- NMNAT1 | c.439+107C>T | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- PABPN1 | c.535-13C>G | Intron (SNP) | VAF 99/408 reads (24%) | catalogued as rs769774240; called by muse, mutect2, varscan2
- PPFIBP2 | c.1376-421del | Intron (DEL) | VAF 65/400 reads (16%) | called by mutect2, pindel, varscan2
- PSMA2 | c.531-11A>T | Intron (SNP) | VAF 40/109 reads (37%) | catalogued as rs773310900; called by mutect2, varscan2
- RCN2 | c.-27C>T | 5'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.-86+4491A>G | Intron (SNP) | VAF 77/416 reads (19%) | called by muse, mutect2, varscan2
- SCNM1 | c.122+9A>T | Intron (SNP) | VAF 50/229 reads (22%) | called by muse, varscan2
- SETDB1 | c.-12+221A>C | Intron (SNP) | VAF 81/325 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.6063C>T | RNA (SNP) | VAF 16/61 reads (26%) | catalogued as rs747961961, COSV50486929; called by muse, mutect2, varscan2
- TRAPPC3 | c.42+29C>T | Intron (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6415G>T | Intron (SNP) | VAF 57/244 reads (23%) | called by muse, mutect2, varscan2
